Gene-level copy-number profile of tumor specimen HCM-BROD-0420-C71-02B from HCMI case HCM-BROD-0420-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 48.3 years (17,653 days).
Specimen HCM-BROD-0420-C71-02B: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file de380bb6-cde4-4c12-b46d-e71b907ec909.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0420-C71-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/3a8d7086-d6a3-4602-a80d-1e2120a9fb42

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 5; copy number 2: 7,523; copy number 3: 6,770; copy number 4: 37,541; copy number 5: 5,251; copy number 6: 1,587; copy number 7: 1; copy number 11: 4; copy number 14: 7; copy number 15: 57; copy number 16: 4; copy number 20: 34; copy number 24: 12; copy number 25: 43; copy number 27: 6; copy number 29: 46.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,453,802–21,559,900, 1 gene (within-gene range 0–2): MIR31HG.
- chr9:21,480,839–22,214,672, 21 genes: IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 213 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:202,940,826–204,562,521, 57 genes, copy number 15: ADIPOR1, CYB5R1, MGAT4FP, AC096632.1, TMEM183A, PPFIA4, MYOG, ADORA1, AC105940.2, AC105940.1, MYBPH, CHI3L1, CHIT1, NPM1P40, LINC01353, LINC01136, BTG2, RNU6-487P, FMOD, AL359837.1, LARP7P1, PRELP, OPTC, ATP2B4, NSA2P1, SNORA77, LAX1, ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3, LINC00303, AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74.
- chr1:217,631,324–217,871,696, 3 genes, copy number 29: SPATA17, SPATA17-AS1, UBBP2.
- chr7:53,926,676–56,491,635, 70 genes, copy number 14–29 (broad region; genes not listed).
- chr7:56,940,341–57,074,664, 6 genes, copy number 27: AC069152.1, MIR4283-1, TNRC18P3, SLC29A4P1, PHKG1P4, AC122133.1.
- chr7:63,556,598–63,636,617, 4 genes, copy number 11: SLC29A4P2, TNRC18P2, MIR4283-2, AC006015.1.
- chr7:89,882,353–94,077,157, 73 genes, copy number 16–29 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
